Somatic mutation profile of tumor specimen TCGA-G9-6371-01A (aliquot TCGA-G9-6371-01A-11D-1786-08) from TCGA case TCGA-G9-6371, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.5 years (21,365 days).
Specimen TCGA-G9-6371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3855d5c4-8018-48e2-8fb7-c6e8943792ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6371-10A (Blood Derived Normal), aliquot TCGA-G9-6371-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2151b5b4-6f9f-4428-86e7-63ccd70e3a6f

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPXM2 | c.1041C>A p.S347R | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53864427; called by muse, varscan2
- EXOC2 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779462173, COSV57867209; called by muse, mutect2, varscan2
- FARSB | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139085353, COSV56050326; called by muse, mutect2, varscan2
- HGF | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472303114, COSV55951602; called by muse, mutect2, varscan2
- KDM5A | c.3515G>T p.G1172V | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66993604; called by muse, mutect2
- LTN1 | c.1523A>C p.D508A | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV63734110; called by muse, mutect2
- MED13 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67261837; called by muse, mutect2, varscan2
- MYH4 | c.5038C>T p.R1680C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149007526, COSV55120484; called by muse, mutect2, varscan2
- NLRP3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs533920557, COSV60221235, COSV60223557; called by muse, mutect2, varscan2
- OR5L2 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV65724376; called by muse, mutect2, varscan2
- SLC4A2 | c.3604G>A p.V1202M | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV52540540; called by muse, mutect2
- SREBF2 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV63331644; called by muse, mutect2, varscan2
- TCN2 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV53191924; called by muse, mutect2, varscan2
- TUBB2B | c.67G>T p.V23F | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV52533985; called by muse, mutect2
- ZFP28 | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56736429; called by muse, mutect2
- IGKV1D-8 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SLC30A4 | c.307_310del p.E103Yfs*2 | Frame Shift Del (DEL) | VAF 28/176 reads (16%) | called by mutect2, pindel, varscan2
- FFAR4 | c.444G>T p.R148= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV65179186; called by muse, mutect2, varscan2
- IFT57 | c.882T>C p.T294= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs143767161; called by muse, mutect2, varscan2
- MGAM | c.3072C>T p.S1024= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as rs375312122, COSV72074934; called by muse, mutect2
- RYR2 | c.9654C>T p.I3218= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs1472161324, COSV63669343, COSV63698625; called by muse, mutect2
- ARHGEF25 | chr12:57610278 G>A | 5'Flank (SNP) | VAF 5/40 reads (13%) | catalogued as rs375023885; called by muse, mutect2, varscan2
